Somatic mutation profile of tumor specimen TARGET-10-PARANN-09A (aliquot TARGET-10-PARANN-09A-01D) from TARGET case TARGET-10-PARANN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (540 days).
Specimen TARGET-10-PARANN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b94e60de-642d-4ff0-ba4d-8f2d180ca298.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARANN-10A (Blood Derived Normal), aliquot TARGET-10-PARANN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b996b91-45a0-4a44-a9a6-eb82464ca6bc

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRACDL | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs759470403; called by muse, varscan2
- MMP16 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.552); catalogued as rs146269135; called by muse, mutect2, varscan2
- PIP5K1B | c.770_771insACCCCG p.R257_V258insPR | In Frame Ins (INS) | VAF 41/103 reads (40%) | called by mutect2, pindel, varscan2
- PRSS55 | c.722A>C p.E241A | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ARNT2 | c.333G>A p.S111= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs761122065; called by muse, mutect2, varscan2
- ZBBX | c.2334A>C p.T778= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
